Surgical pathology report (de-identified scan), TCGA case TCGA-WA-A7GZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Schleswig-Holstein, specimen TCGA-WA-A7GZ-01A (Primary Tumor).

[page 1 of 3]
Date of tumor procurement:

Name

Study Subject ID:

Material / Macroscopy

8. Surgical tumor specimen, ventral marker suture: 3.5 x 4.1 x 4-cm surgical specimen marked with a suture, partly covered in mucous membrane. There is a 3.3 x 2 cm-central ulceration. Minimum distance of the ulceration to the resection margins: 12 mm ventral, questionable dorsal margin, 12 mm to the right, 8 mm to the left. The resection margins have already been examined in the rapid section. Ink marker: ventral blue, dorsal black, left yellow, right orange, depth red. Lamellation from right (yellow ink) to left (orange ink) with 11 lamellae. A relatively clearly definable, 2.9 x 4 x 1.2-cm, rough whitish tumor can be found in lamellae 3 through 10 below the ulceration, which exhibits questionable margins ventrally, dorsally and into the depth in the area of the soft tissue. a) Right-lateral RM (lamella I), b) left-lateral RM (lamella 11).

1/3

100-0-3

Carcinoma, squamous cell, keratinizing NOS 8071/3

Site Floor of mouth NOS 104.9

7/1/13

[page 2 of 3]
Name _____

c) lamella 3 (c1 = ventral portion, c2 = dorsal portion), d) lamella 5 (embedding like lamella 3), e) lamella 7, f) lamella 9
9. Healthy mucosa sample: excised tissue, 0.5 x 0.3 x 0.3 cm in size, one side covered in mucous membrane. Embedded in toto.

Microscopy

(34 blocks H&E, of which 4x decalcification, PAS)

8. Lamellae I and II are both tumor-free. In lamella I, a mucous salivary gland with focal lymphocytic cell infiltrates can be found below a layer of squamous epithelium. These are partly lymphofollicular. Basally, a larger, ectatic duct with focal ulceration includes the epithelial lining. Flat, cushion-shaped, highly vascular granulation tissue with inflammation (location of a concrement?). In lamella 3 (e) sections of the salivary gland with focal, partly moderate lymphofollicular infiltration and periductal fibrosis. Focal lobular atrophy with dense lymphoplasmacellular inflammation and progressive fibrosis. Infiltration of the gland by a squamous cell carcinoma up to a strongly ectatic duct.
In d - f, infiltrates of a squamous cell carcinoma with a superficial ulceration that spreads infiltratively in partially coarse, partially finger-like strands with a strong desmoplastic stromal reaction. Tumor cell complexes include keratinous masses and keratinous pearls to varying degrees. Moderate nuclear pleomorphism. Numerous, partially atypical mitoses. Fragmentation of the complexes, cell separation.
Perineural sleeve infiltration. Infiltration of salivary gland tissue and connective tissue down to a fascicular nerve branch. Maximum in-depth infiltration, 8 mm. No evidence of angioinvasion.
Distance from the resection margin: at least 2 mm to depth, > 5mm to the lateral resection margins.
9. Excised tissue covered with regularly stratified squamous epithelium. Hereunder loose connective tissue and striated musculature without tumor infiltration.

[page 3 of 3]
Name

Diagnosis

8. Surgical specimen from the floor of the mouth (right) with a widely ulcerated, 4 cm, moderately differentiated, keratinizing squamous cell carcinoma. Reticular form of infiltration. Perineural sleeve infiltration. Depth extension 8 mm. No evidence of angioinvasion. The resection was carried out with a minimum distance of 2 mm to depth and > 5 mm at the mucosa level in toto.
9. Tumor-free excised tissue

Source: NCI Genomic Data Commons file bbfed685-1085-4a7c-8a57-581a98a98f0c (TCGA-WA-A7GZ.79B28528-E6A5-494D-96EF-FBF7DAC748FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).